Somatic mutation profile of tumor specimen PCProject_0190_T1_WES (aliquot PCProject_0190_T1_WES_1) from CMI case PCProject_0190, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 48.3 years (17,638 days).
Specimen PCProject_0190_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95f8e339-72f1-4acb-90cc-6fa3d60ee0da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0190_SALIVA (Saliva), aliquot PCProject_0190_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0b78f14-b64e-4536-b7be-b1d08b4fcb7b

The open-access MAF lists 50 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Intron 3, 3'UTR 2, In Frame Ins 1, RNA 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.2342C>T p.A781V | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs72653791, CM054643; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTA2 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as rs121434528, CM075974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 107/180 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMPD1 | c.688A>G p.T230A | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs370874514; called by muse, mutect2, varscan2
- C4orf54 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as rs980910690, COSV101552121; called by muse, mutect2, varscan2
- COL4A1 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as rs758315813; called by muse, mutect2, varscan2
- DLGAP2 | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs780871763; called by muse, mutect2, varscan2
- KCNA3 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772741157, COSV63901019; called by muse, mutect2, varscan2
- LILRB1 | c.1610G>A p.R537H (on ENST00000427581; = p.R487H on NM_006669.6) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs564223169, COSV61117758; called by muse, varscan2
- MSRA | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs771277551, COSV100412542; called by muse, mutect2, varscan2
- NCAN | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370512552; called by muse, mutect2, varscan2
- NSMAF | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs147647770; called by muse, mutect2, varscan2
- PDE6B | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760089278; called by muse, mutect2, varscan2
- POTEC | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as COSV62805227; called by muse, mutect2, varscan2
- SLC22A25 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as rs748557797; called by mutect2, varscan2
- SLC2A10 | c.509G>T p.W170L | Missense Mutation (SNP) | VAF 107/307 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV63715335; called by muse, mutect2, varscan2
- SLCO2B1 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754251441, COSV99214159; called by muse, mutect2, varscan2
- TNN | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1486997748; called by muse, mutect2, varscan2
- WDR72 | c.62C>A p.T21N | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV64741298; called by muse, mutect2, varscan2
- ALDH9A1 | c.937_938insACT p.C312_C313insY | In Frame Ins (INS) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- ATP6V0A4 | c.2292C>G p.N764K | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CASP5 | c.1096+2T>A p.X366_splice | Splice Site (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- CEP295 | c.7246T>G p.F2416V | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- DNAH3 | c.12199T>C p.C4067R | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FANCF | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 126/361 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- GRAMD1C | c.1937A>C p.K646T | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, varscan2
- HIF1A | c.504dup p.L169Sfs*9 | Frame Shift Ins (INS) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- KCNG4 | c.1211G>A p.S404N | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGBD2 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PGBD2 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SKOR1 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.097); called by mutect2, varscan2
- STX19 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SULT2B1 | c.26T>C p.I9T | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACLY | c.2721C>T p.A907= | Silent (SNP) | VAF 34/153 reads (22%) | catalogued as rs978298950; called by muse, mutect2, varscan2
- ANK2 | c.228C>T p.H76= | Silent (SNP) | VAF 39/298 reads (13%) | catalogued as rs1300920995; called by muse, mutect2, varscan2
- CGB3 | c.306C>T p.Y102= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs756000922; called by mutect2, varscan2
- CORO2B | c.894C>T p.Y298= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as rs141982749; called by muse, mutect2, varscan2
- DOCK3 | c.417G>A p.V139= | Silent (SNP) | VAF 19/191 reads (10%) | catalogued as rs985667778; called by muse, mutect2
- KCNK17 | c.309C>T p.L103= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs759291342, COSV64678053; called by muse, mutect2, varscan2
- LOXL2 | c.615C>T p.Y205= | Silent (SNP) | VAF 46/312 reads (15%) | catalogued as rs1301395599, COSV66690290; called by muse, mutect2, varscan2
- SMARCA2 | c.687G>A p.Q229= | Silent (SNP) | VAF 36/210 reads (17%) | catalogued as rs774478658, COSV61807589; called by muse, varscan2
- WDR87 | c.3405C>T p.S1135= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs769535176; called by muse, mutect2, varscan2
- YTHDC2 | c.3168G>A p.T1056= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs765103151, COSV50739645, COSV50740354; called by muse, mutect2, varscan2
- ZCWPW1 | c.978C>T p.Y326= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs775065135, COSV100228499; called by muse, mutect2, varscan2
- CBY1 | c.78+9C>T | Intron (SNP) | VAF 24/85 reads (28%) | catalogued as rs376944012; called by muse, mutect2, varscan2
- HNRNPU | c.634+932T>A | Intron (SNP) | VAF 25/149 reads (17%) | called by muse, mutect2, varscan2
- HPN | c.*19G>A | 3'UTR (SNP) | VAF 19/72 reads (26%) | catalogued as rs774390341; called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.159C>T | RNA (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- TMBIM4 | c.97+563T>G | Intron (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- ZNF747 | c.*448G>A | 3'UTR (SNP) | VAF 15/65 reads (23%) | catalogued as rs1227496059; called by muse, mutect2, varscan2
